Somatic mutation profile of tumor specimen C3N-01381-01 (aliquot CPT0094130010) from CPTAC case C3N-01381, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 43.1 years (15,744 days).
Specimen C3N-01381-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323869e9-b349-4147-8f6b-f160cb2b9b68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01381-31 (Blood Derived Normal), aliquot CPT0094170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53b22605-2590-4889-b7ba-b20931497b4e

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 2, Intron 2, RNA 1, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 42/343 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 18/252 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CDKN2A | c.266del p.G89Afs*57 | Frame Shift Del (DEL) | VAF 36/363 reads (10%) | catalogued as CM083605, COSV100448493, COSV58690485; called by mutect2, pindel
- FCGBP | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 23/465 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs747176936; called by muse, mutect2
- FZD9 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59989859; called by muse, mutect2, varscan2
- INHBA | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 34/267 reads (13%) | catalogued as COSV54219472, COSV54224848, COSV54226824; called by muse, mutect2, varscan2
- ENPP4 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FAM163B | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KL | c.2681A>G p.Y894C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO9A | c.3798dup p.V1267Sfs*5 | Frame Shift Ins (INS) | VAF 18/180 reads (10%) | called by mutect2, pindel
- NT5C1B | c.83del p.K28Rfs*10 | Frame Shift Del (DEL) | VAF 17/203 reads (8%) | called by mutect2, pindel
- RNF217 | c.916A>G p.I306V (on ENST00000521654 / NM_001286398.2; = p.I14V on NM_152553.5) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.071); called by muse, mutect2
- RTEL1 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TARM1 | c.480G>T p.L160F (on ENST00000616041 / NM_001330650.1; = p.L152F on NM_001135686.3) | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCLK1 | c.84C>T p.N28= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs373323934; called by muse, mutect2
- FBXW5 | c.1074C>T p.L358= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs1224111797; called by muse, varscan2
- GORASP2 | c.369T>G p.P123= | Silent (SNP) | VAF 24/190 reads (13%) | called by muse, mutect2, varscan2
- ISM1 | c.1308C>A p.A436= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV52604606; called by muse, mutect2, varscan2
- RCSD1 | c.1023G>A p.E341= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29701504 A>G | 3'Flank (SNP) | VAF 211/667 reads (32%) | called by muse, mutect2, varscan2
- DCHS2 | n.8299C>T | RNA (SNP) | VAF 14/193 reads (7%) | catalogued as rs771060100, COSV100600869, COSV61769423; called by muse, mutect2
- FOXP2 | c.*124C>T | 3'UTR (SNP) | VAF 22/328 reads (7%) | called by muse, mutect2
- PLA2G6 | c.2203-26C>T | Intron (SNP) | VAF 37/295 reads (13%) | catalogued as rs928536988; called by muse, mutect2, varscan2
- PTK7 | c.-13T>G | 5'UTR (SNP) | VAF 16/154 reads (10%) | catalogued as rs755952591; called by muse, mutect2
- PTS | c.314+30G>A | Intron (SNP) | VAF 28/311 reads (9%) | called by muse, mutect2
